Gene-level copy-number profile of tumor specimen TCGA-AG-3592-01A from TCGA case TCGA-AG-3592, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.8 years (25,141 days).
Specimen TCGA-AG-3592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.0a826fa9-a55a-44f3-b743-faf4cea3844d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3592-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bef27e9b-2892-466b-b9d6-d39f6e3acd0d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 779; copy number 2: 5,850; copy number 3: 30,827; copy number 4: 15,537; copy number 5: 879; copy number 6: 2,107; copy number 7: 1,715; copy number 8: 1,355; copy number 9: 757.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3592-01A-02D-1732-01): tumor purity 0.7, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,935,353–4,994,972, 1 gene (within-gene range 0–1): CSMD1.
- chr8:3,700,492–4,788,584, 5 genes: RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4.
- chr8:5,363,371–5,363,650, 1 gene: AC007718.1.
- chr16:5,838,131–5,838,661, 1 gene: AC012175.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,827 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–65,554,744, 1,213 genes, copy number 8 (broad region; genes not listed).
- chr9:14,475–22,455,740, 324 genes, copy number 7 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 7 (broad region; genes not listed).
- chr20:25,407,673–51,768,390, 639 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:54,475,593–60,653,784, 118 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:61,252,261–61,940,617, 1 gene, copy number 8 (within-gene range 5–8): CDH4.
- chr20:61,432,868–64,313,132, 141 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
